Somatic mutation profile of tumor specimen TCGA-P5-A5EU-01A (aliquot TCGA-P5-A5EU-01A-11D-A27K-08) from TCGA case TCGA-P5-A5EU, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 35.2 years (12,851 days).
Specimen TCGA-P5-A5EU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 98177903-1452-464e-9e5f-6c93c1589e5f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-P5-A5EU-10A (Blood Derived Normal), aliquot TCGA-P5-A5EU-10A-01D-A27N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8159ff4d-2fe4-4daf-93b7-eba641216f01

The open-access MAF lists 27 somatic variants for this specimen: 20 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 16, Silent 7, Splice Site 2, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 33/87 reads (38%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3R1 | c.1690A>G p.N564D (on ENST00000521381 / NM_181523.3; = p.N294D on NM_181504.4) | Missense Mutation (SNP) | VAF 56/114 reads (49%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.671); catalogued as rs1057519841, COSV57124003; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.569C>G p.P190R | Missense Mutation (SNP) | VAF 59/69 reads (86%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs876660825, CM161004, COSV52664064, COSV52987047, COSV53313892; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AMIGO2 | c.1395A>T p.R465S | Missense Mutation (SNP) | VAF 31/38 reads (82%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as COSV56975405; called by muse, mutect2, varscan2
- ANKRD34B | c.1313A>G p.D438G | Missense Mutation (SNP) | VAF 78/191 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.859); catalogued as COSV58614438; called by muse, mutect2, varscan2
- APOB | c.13153C>T p.R4385C | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as rs864309556, CM125433, COSV51949532; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C8A | c.332G>A p.R111H | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs753968787, COSV63486112; called by muse, mutect2, varscan2
- DAGLA | c.1396C>G p.L466V | Missense Mutation (SNP) | VAF 146/333 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV57199148; called by muse, mutect2, varscan2
- DTX1 | c.1189C>T p.R397* | Nonsense Mutation (SNP) | VAF 4/12 reads (33%) | catalogued as rs747945791, COSV57496012; called by muse, mutect2
- GPR78 | c.425T>G p.L142R | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV66763434, COSV66763868; called by muse, mutect2, varscan2
- LGALS2 | c.90-2A>G p.X30_splice | Splice Site (SNP) | VAF 46/109 reads (42%) | catalogued as rs1471404237, COSV50758298; called by muse, mutect2, varscan2
- NT5C | c.206G>A p.G69D | Missense Mutation (SNP) | VAF 52/125 reads (42%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.47); catalogued as COSV55461946; called by muse, mutect2, varscan2
- OTOS | c.59-1G>A p.X20_splice | Splice Site (SNP) | VAF 24/34 reads (71%) | catalogued as rs945454245, COSV56228834; called by muse, varscan2
- PLCB2 | c.2570G>A p.G857E | Missense Mutation (SNP) | VAF 27/40 reads (68%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV53037372, COSV99542724; called by muse, mutect2, varscan2
- RPE65 | c.998G>T p.G333V | Missense Mutation (SNP) | VAF 135/349 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1173207597, COSV52018177, COSV99254017; called by muse, mutect2, varscan2
- RTP2 | c.569C>T p.A190V | Missense Mutation (SNP) | VAF 54/137 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.024); catalogued as rs569180222, COSV64078930; called by muse, mutect2, varscan2
- TOP1MT | c.1697T>C p.I566T | Missense Mutation (SNP) | VAF 56/146 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as rs759840706, COSV61319554; called by muse, mutect2, varscan2
- TSHZ2 | c.2179T>C p.S727P | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV61591018; called by muse, mutect2, varscan2
- ZAP70 | c.1475A>G p.Y492C | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53856695; called by muse, mutect2
- ATRX | c.3956_3957del p.Q1319Rfs*4 | Frame Shift Del (DEL) | VAF 8/10 reads (80%) | called by mutect2, varscan2
- DSG4 | c.2607T>A p.P869= | Silent (SNP) | VAF 77/183 reads (42%) | catalogued as COSV57396694; called by muse, mutect2, varscan2
- EPPK1 | c.4509C>T p.S1503= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as rs782373090, COSV73262307; called by muse, mutect2, varscan2
- MPZ | c.741G>A p.K247= | Silent (SNP) | VAF 48/112 reads (43%) | catalogued as COSV60669149; called by muse, mutect2, varscan2
- MUC3A | c.8655C>T p.G2885= | Silent (SNP) | VAF 65/399 reads (16%) | catalogued as rs765876494, COSV60216265; called by muse, mutect2
- OR4C13 | c.132G>T p.V44= | Silent (SNP) | VAF 132/298 reads (44%) | catalogued as rs782692565, COSV73648792; called by muse, mutect2, varscan2
- RSBN1 | c.2031C>T p.F677= | Silent (SNP) | VAF 41/109 reads (38%) | catalogued as COSV54731326; called by muse, mutect2, varscan2
- STX11 | c.636C>T p.R212= | Silent (SNP) | VAF 41/56 reads (73%) | catalogued as COSV62450201; called by muse, mutect2, varscan2
